Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A703, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A703-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology

Final Results

Surgical Pathology

Final

CASE NUMBER:

DIAGNOSIS: Right adrenal mass (excision): Pheochromocytoma with areas suggestive of diverged differentiation.

NOTE: Immunohistochemistry studies were performed and were positive for Chromogranin, Synaptophysin and S-100 and negative for C-Kit and NTFP.

The case was reviewed by

The immunoperoxidase tests performed here were developed and their performance characteristics determined by the Specialized Diagnostics Unit of the Laboratory of Pathology. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: pt with VHL Requestor Name

Requestor Phone/Pager: Specimen Taken For
Protocol: 01 - Yes
Allocate Order to Protocol:

PROCEDURE: Operative Findings: Large right renal mass Post-Operative Diagnosis:
pheochromocytoma Pre-Operative Diagnosis: Pheochromocytoma

SPECIMENS SUBMITTED: 1. ADRENAL MASS, RIGHT

GROSS DESCRIPTION: Received is a single formalin filled container labeled with the patient's name, medical record number and "right adrenal mass". The specimen consists of an 8.7 x 6.1 x 3.6 cm red/brown nodular piece of tissue with a ribbon of golden-appearing tissue measuring 2.2 x 0.4 cm, grossly consistent with normal adrenal. The specimen weighs 90.5 grams. Further examination of the specimen reveals that the main tumor mass is 6.7 x 6.0 x 3.5 cm with an additional rim of tissue grossly resembling normal adrenal measuring 7.2 cm in length x 0.6 cm. The external surface is entirely inked in black and the specimen is bisected to reveal a variegated brown, tan and yellow cut surface with area of deep red measuring 2.8 cm in greatest dimensions. Central portions of the tumor measuring 5.0 x 3.0 x 1.0 cm in aggregate are procured for . A central portion of tumor, measuring 1.5 x 0.5 x 0.3 cm, is procured for . Small sections of grossly normal-appearing adrenal measuring 0.6 x 0.3 x 0.3 cm are procured for . The procurement was done by on , the specimen is received as noted above and representative sections are submitted in white cassettes for permanent processing as follows:

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974

Requested By:

Do not file in Medical Record

[page 2 of 2]
Final Results

Surgical Pathology

tumor with capsule
tumor with relation to normal
normal,
area of hemorrhage and firm white area

Gross dictated by

No consultants

#

#

Criteria	Law 7/25/12	No
Hx/PA Discrepancy		✓
Dr. J/C synchronous Primary Notes		

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974

Requested By:

Do not file in Medical Record

Source: NCI Genomic Data Commons file 44856b55-4f62-4eda-9148-0b672853b446 (TCGA-QR-A703.0702773F-DD32-4CC2-A20C-EDC9877A6673.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).